Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4165, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4165-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

1: SP: Right kidney [REDACTED]

2: SP: Paracaval nodule [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE I/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 5.5 CM.
- THE TUMOR EXTENDS INTO THE RENAL PELVIS.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS BENIGN SIMPLE CORTICAL CYST.
- INCIDENTAL ANGIOMYOLIPOMA, SIZE 0.2 CM.

- 2) LYMPH NODE, PARACAVAL; EXCISION:
- BENIGN LYMPH NODES (0/2).
- [REDACTED]
- [REDACTED]

Gross Description:

[REDACTED]

1) The specimen is received fresh for frozen section, labeled, "Right kidney". It consists of a 13.0 x 8.0 x 4.5 cm kidney with attached renal fat ranging in thickness from 0.2 up to 4.0 cm. The perirenal fat received and reflected from the surface of the kidney. The attached ureter measures in length, 7.0 cm. The surgical margin is stapled. The vessels are unremarkable and stapled, ligated in the hilum. The attached length of the artery measures 1.5 cm. The renal vein at the hilum measures 0.7 x 0.9 x 0.3 cm. In the mid/lower portion of the specimen, the capsule is bulging. At this area, the capsule is inked. Representative section of the specimen is submitted for frozen. On cut surface, there is a 5.5 x 5.0 x 3.0 cm orange, yellow, soft mass with central hemorrhage and cystic degeneration. The mass appears to extend into the renal pelvis. The mass doesn't appear infiltrate through the renal capsule although it abuts it. The remainder of the renal parenchyma is tan, brown, unremarkable with the renal cortex measuring 0.5 cm in general thickness and the renal medulla measuring 2.0 cm. There are no lymph node identified in the perihilar fat. Specimen is photographed. Representative sections of the specimen are submitted for TPS.

Summary of Sections:

FSC - frozen section control

UM - ureter margin

VM - vascular margin

TUC - tumor of the capsule

TRP - tumor to renal pelvis

[page 2 of 2]
TNL- tumor, normal
TH - tumor, hemorrhagic
TCYS - tumor, cystic
UP - upper pole
MP - mid portion
LP - lower pole
PHF - perihilar fat

2) The specimen is received in formalin, labeled, "Paracaval nodule". It consists of a 2.9 x 1.6 x 0.7 cm fatty fragment containing two lymph nodes, the smaller is 0.6 x 0.5 x 0.5 cm and the larger is 1.6 x 0.8 x 0.5 cm. Bisected and entirely submitted.

Summary of Sections:
BLN - bisected lymph node

Summary of Sections:

Part 1: SP: Right kidney

Block	Sect. Site	PCs
1	FSC	1
1	LP	1
1	MP	1
1	PHF	1
1	TCYS	1
1	TH	1
1	TNL	1
1	TRP	1
3	TUC	3
1	UM	1
1	UP	1
1	VM	3

Part 2: SP: Paracaval nodule

Block	Sect. Site	PCs
1	BLN1	2
1	BLN2	2

Intraoperative Consultation:

Note: The diagnosis given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 25c3d450-75ac-40b3-a886-1e1b30f3d080 (TCGA-BP-4165.F7D646C1-9055-46C2-A557-3F518F5FFE39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).